Somatic mutation profile of tumor specimen TCGA-J8-A3NZ-01A (aliquot TCGA-J8-A3NZ-01A-11D-A21A-08) from TCGA case TCGA-J8-A3NZ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 52.2 years (19,058 days).
Specimen TCGA-J8-A3NZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6af7247e-44fc-4bc7-9b8c-50960fb97004.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J8-A3NZ-10A (Blood Derived Normal), aliquot TCGA-J8-A3NZ-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f94a573-08cc-428f-9027-383de45cd681

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BDH1 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs145598252; called by muse, mutect2, varscan2
- BCAM | c.879G>A p.G293= | Silent (SNP) | VAF 88/183 reads (48%) | catalogued as COSV54301395; called by muse, mutect2, varscan2
- CFAP91 | c.1726C>T p.L576= | Silent (SNP) | VAF 64/138 reads (46%) | catalogued as rs982551289, COSV56340151; called by muse, mutect2, varscan2
- GJA4 | c.957C>G p.P319= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV60725144; called by muse, mutect2, varscan2
